Somatic mutation profile of tumor specimen 0DIW85 from CCDI case PBBWED, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.1 years (2,220 days).
Specimen 0DIW85: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbfced58-d2e8-4b93-b0d8-b9683f9a918d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIW68 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8e21b12-b192-4129-9202-4bd82d7dcbf2

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Ins 2, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 195/562 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs147316535; called by muse, mutect2, varscan2
- CHTF18 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 212/622 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs767399733; called by muse, mutect2, varscan2
- GPSM1 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 275/921 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs146149038; called by muse, mutect2, varscan2
- SNTG2 | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 276/817 reads (34%) | catalogued as COSV57967500; called by muse, mutect2, varscan2
- TP53 | c.370dup p.C124Lfs*25 | Frame Shift Ins (INS) | VAF 311/597 reads (52%) | catalogued as COSV52717910, COSV53118583; called by mutect2, pindel, varscan2
- SPEN | c.10731_10732dup p.A3578Gfs*13 | Frame Shift Ins (INS) | VAF 183/743 reads (25%) | called by mutect2, pindel, varscan2
- HELZ2 | c.6909C>G p.T2303= (on ENST00000467148 / NM_001037335.2; = p.T1734= on NM_033405.3) | Silent (SNP) | VAF 288/923 reads (31%) | called by muse, mutect2, varscan2
- PPFIA3 | c.316C>T p.L106= | Silent (SNP) | VAF 38/820 reads (5%) | called by muse, mutect2
- SKIV2L | c.3399+45del | Intron (DEL) | VAF 82/309 reads (27%) | called by mutect2, pindel, varscan2
